Somatic mutation profile of tumor specimen TCGA-OR-A5JB-01A (aliquot TCGA-OR-A5JB-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JB, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 52.5 years (19,172 days).
Specimen TCGA-OR-A5JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddac6629-e93a-4551-aa61-3c3b013d7177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JB-10A (Blood Derived Normal), aliquot TCGA-OR-A5JB-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ed35f19-b184-42ba-85d3-9b6bd0552a93

The open-access MAF lists 336 somatic variants for this specimen: 252 protein-altering or splice-affecting, 75 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 75, Nonsense Mutation 25, Splice Site 8, Frame Shift Del 7, RNA 6, Frame Shift Ins 2, Splice Region 1, Translation Start Site 1, 3'UTR 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3703C>T p.Q1235* | Nonsense Mutation (SNP) | VAF 62/94 reads (66%) | catalogued as rs1555615109, CM041403, COSV62219230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.2174+1G>A p.X725_splice | Splice Site (SNP) | VAF 112/401 reads (28%) | catalogued as rs267608172, CS083966, COSV56222103; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 41/65 reads (63%) | hotspot (GDC flag); catalogued as rs1131690940, CM991157, COSV58820792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTR5 | c.789G>T p.W263C | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781400177; called by muse, mutect2, varscan2
- ADAM15 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 160/418 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs768973456; called by muse, mutect2, varscan2
- ADAM30 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs200088734, COSV65561660; called by muse, mutect2, varscan2
- ADCY2 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358146800, COSV57894017; called by muse, mutect2, varscan2
- ADGRL4 | c.1350G>T p.W450C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs755271420; called by muse, mutect2, varscan2
- ANK2 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99999276; called by muse, mutect2, varscan2
- ATP1A4 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV63627304; called by muse, mutect2, varscan2
- BCAN | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 107/543 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377573150, COSV61256643; called by muse, mutect2, varscan2
- C1orf54 | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs781793956; called by muse, mutect2, varscan2
- C5orf49 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs202097565; called by muse, mutect2, varscan2
- CBL | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.274); catalogued as COSV50649368; called by muse, mutect2, varscan2
- CCDC170 | c.1722G>T p.L574F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99498480; called by muse, mutect2, varscan2
- CCSER1 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.907); catalogued as COSV61402573, COSV61433484; called by muse, mutect2, varscan2
- CLEC5A | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV69397878; called by muse, mutect2, varscan2
- CNTNAP5 | c.1257C>A p.S419R | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.141); catalogued as rs934010795; called by muse, mutect2, varscan2
- CNTNAP5 | c.2890G>T p.G964C | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101443139; called by muse, mutect2, varscan2
- CNTNAP5 | c.3435G>A p.E1145= | Splice Region (SNP) | VAF 30/78 reads (38%) | catalogued as COSV70507737, COSV70511265; called by muse, mutect2, varscan2
- CSMD3 | c.32C>A p.A11E | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.306); catalogued as COSV99829417; called by muse, mutect2, varscan2
- CUL3 | c.380A>T p.D127V | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100024267; called by muse, mutect2, varscan2
- DCAF11 | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.95); catalogued as COSV58110022; called by muse, mutect2, varscan2
- DCLK1 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as rs535509328; called by muse, mutect2, varscan2
- DENND4C | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV66821923; called by muse, mutect2, varscan2
- DIAPH3 | c.1768C>G p.P590A (on ENST00000400324 / NM_001042517.2; = p.P327A on NM_030932.3) | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV57373789; called by muse, mutect2, varscan2
- FAM81B | c.657-1G>C p.X219_splice | Splice Site (SNP) | VAF 76/180 reads (42%) | catalogued as COSV51987441; called by muse, mutect2, varscan2
- FANCM | c.3704G>T p.G1235V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs146490925; called by muse, mutect2, varscan2
- FAT4 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 146/256 reads (57%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as rs758125798, COSV67896765; called by muse, mutect2, varscan2
- FBN1 | c.7540G>T p.G2514* | Nonsense Mutation (SNP) | VAF 105/230 reads (46%) | catalogued as CM025900, CM077253, COSV57326105; called by muse, mutect2, varscan2
- FIBIN | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs749074974; called by muse, mutect2, varscan2
- FLG | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV64249223; called by muse, mutect2, varscan2
- FOXG1 | c.958C>A p.R320S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as rs1462696621, COSV57399309; called by muse, mutect2, varscan2
- FPR1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494057; called by muse, mutect2, varscan2
- FRMPD1 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV66700930; called by muse, mutect2, varscan2
- FYB1 | c.2251G>A p.E751K (on ENST00000351578 / NM_199335.5; = p.E797K on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs1054969715, COSV60955083; called by muse, mutect2, varscan2
- GABRA2 | c.1256G>C p.R419T | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV62917045; called by muse, mutect2, varscan2
- GABRB3 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as COSV54657666; called by muse, mutect2, varscan2
- GPATCH2 | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV65127696, COSV65127833; called by muse, mutect2, varscan2
- GRIK1 | c.1718C>A p.P573H | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749497254; called by muse, mutect2, varscan2
- H3C7 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV55099822, COSV55101039; called by muse, mutect2, varscan2
- HAUS5 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1286187650; called by muse, mutect2, varscan2
- HERC2 | c.9164-2A>G p.X3055_splice | Splice Site (SNP) | VAF 46/108 reads (43%) | catalogued as COSV55321210; called by muse, mutect2, varscan2
- HLA-F | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1412661084; called by muse, mutect2, varscan2
- HRNR | c.5734C>A p.Q1912K | Missense Mutation (SNP) | VAF 226/3805 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs753059786, COSV64261005; called by muse, mutect2
- HSPA12A | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65020721; called by muse, mutect2, varscan2
- IGKV1-17 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs377554639; called by muse, mutect2, varscan2
- IKZF1 | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV58788135; called by muse, mutect2, varscan2
- IL18R1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746216073; called by muse, mutect2, varscan2
- INO80 | c.3075C>G p.Y1025* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV100731516; called by muse, mutect2, varscan2
- KCNB1 | c.1723C>G p.R575G | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV65567537; called by muse, mutect2, varscan2
- KIAA1109 | c.13124G>A p.R4375Q | Missense Mutation (SNP) | VAF 95/154 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs377061438; called by muse, mutect2, varscan2
- KRT75 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV52872015; called by muse, mutect2, varscan2
- LCE4A | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as rs773952427; called by muse, mutect2, varscan2
- LHX6 | c.424G>T p.D142Y (on ENST00000373755 / NM_001242334.2; = p.D171Y on NM_014368.5) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61344682; called by muse, mutect2, varscan2
- LRRC4C | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV53431599, COSV99538521; called by muse, mutect2, varscan2
- MARCO | c.509del p.P170Rfs*94 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs1162388049; called by mutect2, varscan2
- MARK1 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 131/173 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV65069679; called by muse, mutect2, varscan2
- MC3R | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 168/463 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs776825272; called by muse, mutect2, varscan2
- MSH2 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs139891783, CD045346; called by muse, mutect2, varscan2
- NLRP8 | c.1664T>A p.M555K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748024796; called by muse, mutect2, varscan2
- NRG3 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV64551792, COSV64562656; called by muse, mutect2, varscan2
- NYAP2 | c.1263C>G p.Y421* | Nonsense Mutation (SNP) | VAF 58/187 reads (31%) | catalogued as COSV56018895; called by muse, mutect2, varscan2
- OAS1 | c.489T>G p.Y163* | Nonsense Mutation (SNP) | VAF 69/188 reads (37%) | catalogued as COSV52535522; called by muse, mutect2, varscan2
- OR5B12 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV56907099; called by muse, mutect2, varscan2
- OSMR | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1254938033; called by muse, varscan2
- P2RY14 | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs919759435; called by muse, mutect2
- PDCD5 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV55678335; called by muse, mutect2, varscan2
- PIWIL1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV55349552; called by muse, mutect2, varscan2
- POT1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777475, CM144558, COSV62931229, COSV62935193; called by muse, mutect2, varscan2
- POTEF | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 58/477 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs759001401, COSV62540544, COSV62543242; called by muse, varscan2
- PRX | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52527561; called by muse, mutect2, varscan2
- RUNDC3B | c.833T>A p.L278H | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100407260; called by muse, mutect2, varscan2
- SDS | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs373115603; called by muse, mutect2, varscan2
- SEC24B | c.3017T>C p.L1006P | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs904100071; called by muse, mutect2, varscan2
- SEMA3D | c.793C>A p.R265S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.93); catalogued as rs770642273, COSV52394083; called by muse, mutect2, varscan2
- SERPINB11 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 69/120 reads (58%) | catalogued as COSV66958055; called by muse, mutect2, varscan2
- SETBP1 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1369732807; called by muse, mutect2, varscan2
- SGIP1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV52777838; called by muse, mutect2, varscan2
- SLC12A3 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as CM076527, COSV52635146; called by muse, mutect2, varscan2
- SLC27A1 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV53101166; called by muse, mutect2, varscan2
- SLC44A5 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100902601, COSV63763805; called by muse, mutect2, varscan2
- SPHKAP | c.1604C>A p.A535E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755247779; called by muse, mutect2, varscan2
- ST18 | c.1612C>G p.P538A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV52485930; called by muse, mutect2, varscan2
- STAB2 | c.4537G>T p.E1513* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as rs1297575143; called by muse, mutect2, varscan2
- TBC1D21 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); catalogued as COSV55996178; called by muse, mutect2, varscan2
- TLN2 | c.4873A>T p.N1625Y | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60890003; called by muse, mutect2, varscan2
- TMEM138 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs934955921; called by muse, mutect2, varscan2
- TRPM8 | c.2095C>G p.L699V | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61225061; called by muse, mutect2, varscan2
- TSHZ2 | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100295370; called by muse, mutect2, varscan2
- TTLL5 | c.3676G>A p.V1226I | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs903375968, COSV54034543, COSV54042644; called by muse, mutect2, varscan2
- UBE3B | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1444149259; called by muse, varscan2
- XRRA1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs745942861, COSV100369552, COSV58500089; called by muse, mutect2, varscan2
- ZEB2 | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 81/290 reads (28%) | catalogued as COSV57951228; called by muse, mutect2, varscan2
- ZKSCAN3 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV52853599; called by muse, mutect2, varscan2
- ZNF628 | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as rs369974817; called by muse, mutect2
- ZNF793 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs375136979, COSV101495625; called by mutect2, varscan2
- ZRANB2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV54674223; called by muse, mutect2, varscan2
- AASDHPPT | c.331C>A p.H111N | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB1 | c.1634T>A p.L545Q | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSL1 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ACTN1 | c.1804G>A p.G602S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACVR1 | c.725A>T p.E242V | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS17 | c.2041G>T p.G681W | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADGRE3 | c.1389G>T p.M463I | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.425); called by muse, mutect2
- ADGRG4 | c.5242G>A p.E1748K | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL4 | c.1349G>T p.W450L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADSS1 | c.800A>C p.Y267S | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ALDH5A1 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ANK3 | c.3540+1G>T p.X1180_splice (on ENST00000280772 / NM_001320874.2; = p.X314_splice on NM_001149.3) | Splice Site (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- ANKRD28 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- APBA1 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOB | c.8492C>A p.S2831Y | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF2 | c.3948G>A p.M1316I | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASXL3 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- BRSK2 | c.1495G>T p.V499F | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- BSN | c.5909G>T p.R1970M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- C10orf120 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf50 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2
- CACNA1F | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CALCA | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK13 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP250 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2, varscan2
- CHD2 | c.1897C>G p.L633V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CHPT1 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CLEC4F | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CLUH | c.1330G>T p.A444S (on ENST00000435359; = p.A482S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTLN | c.3388A>T p.K1130* | Nonsense Mutation (SNP) | VAF 91/296 reads (31%) | called by muse, mutect2, varscan2
- CSPG4 | c.5358T>A p.Y1786* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- DACT1 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH1 | c.11659G>T p.D3887Y | Missense Mutation (SNP) | VAF 63/106 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNMT3L | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, varscan2
- DRC7 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- DST | c.21105G>T p.R7035S (on ENST00000361203 / NM_001374722.1; = p.R4732S on NM_015548.5) | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ELAVL2 | c.722dup p.N241Kfs*18 | Frame Shift Ins (INS) | VAF 37/119 reads (31%) | called by mutect2, pindel, varscan2
- ELAVL2 | c.488-2A>T p.X163_splice | Splice Site (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- ELP1 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ENC1 | c.1711G>T p.V571F | Missense Mutation (SNP) | VAF 124/382 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EPHA10 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ERG | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ERICH3 | c.3381G>C p.E1127D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ETV1 | c.752_753delinsT p.P251Lfs*4 | Frame Shift Del (DEL) | VAF 65/232 reads (28%) | called by pindel, varscan2*
- FAM90A1 | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2
- FBH1 | c.3064_3065del p.A1022Hfs*14 (on ENST00000362091 / NM_178150.3; = p.A1073Hfs*14 on NM_032807.4) | Frame Shift Del (DEL) | VAF 62/236 reads (26%) | called by pindel, varscan2
- FERD3L | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- FEZF1 | c.983G>T p.S328I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXP2 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FRMPD4 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- FSTL5 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAS8 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- GAS8 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 89/381 reads (23%) | called by muse, mutect2
- GLRA1 | c.751del p.Y251Tfs*2 | Frame Shift Del (DEL) | VAF 109/314 reads (35%) | called by mutect2, pindel, varscan2
- GNAS | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- GPR19 | c.616T>A p.W206R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRM6 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- H2BC15 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAVCR1 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HIPK3 | c.1847G>T p.C616F | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HK3 | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HKDC1 | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IGHM | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- IGKV1D-17 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- IL17A | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL1 | c.1414+2T>A p.X472_splice | Splice Site (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- KPNA5 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- KRTAP10-8 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRTAP24-1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LILRB5 | c.1496G>T p.G499V (on ENST00000449561 / NM_001081442.3; = p.G498V on NM_006840.5) | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LRFN3 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LRFN5 | c.180C>G p.D60E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- LRIT2 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 128/337 reads (38%) | called by muse, mutect2, varscan2
- LUZP2 | c.767del p.P256Lfs*38 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- MED4 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.27876G>C p.E9292D | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MUC16 | c.16069A>T p.S5357C | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MUC16 | c.9497C>A p.T3166N | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUS81 | c.952A>G p.R318G | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MYOM3 | c.4040T>A p.M1347K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- NBEAL1 | c.7714C>T p.H2572Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NECTIN1 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NELFB | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- NEXMIF | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIPAL3 | c.865G>C p.A289P | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NLRP5 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR13C3 | c.1034C>A p.P345Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR13D1 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR1J4 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- OR51E1 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- OR52E6 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR52L1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2
- OR6V1 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR9K2 | c.283G>T p.D95Y (on ENST00000305377; = p.D73Y on NM_001005243.1) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAMR1 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA3 | c.266G>T p.R89M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCLO | c.1825A>T p.T609S | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PITX2 | c.246G>C p.K82N (on ENST00000354925 / NM_001204397.1; = p.K89N on NM_000325.6) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PKHD1 | c.1744T>C p.F582L | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PLCB4 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRAMEF4 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 115/1086 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2
- PRDM9 | c.2620A>T p.S874C | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PSMD6 | c.217A>T p.M73L | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, varscan2
- PTGDS | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- PXDN | c.3497G>T p.G1166V | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PXDNL | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2694del p.F898Lfs*2 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel, varscan2
- RAPGEF3 | c.2581+2T>A p.X861_splice (on ENST00000389212; = p.X819_splice on NM_006105.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 68/190 reads (36%) | called by muse, mutect2, varscan2
- RBM15B | c.2086A>T p.K696* | Nonsense Mutation (SNP) | VAF 112/189 reads (59%) | called by muse, mutect2, varscan2
- RC3H2 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- RCVRN | c.578T>A p.V193E | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.257); called by muse, mutect2
- REC114 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF2 | c.833C>G p.S278* | Nonsense Mutation (SNP) | VAF 100/280 reads (36%) | called by muse, varscan2
- ROBO2 | c.3412G>T p.A1138S | Missense Mutation (SNP) | VAF 86/151 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- S1PR4 | c.873G>T p.W291C | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCN8A | c.3454G>C p.E1152Q | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SDS | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SEPTIN6 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA12 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SETBP1 | c.2689T>A p.C897S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SETBP1 | c.2795G>T p.S932I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- SF3B1 | c.3692T>C p.M1231T | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SF3B4 | c.164-2A>T p.X55_splice | Splice Site (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- SLC13A1 | c.1412G>T p.W471L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SLC1A1 | c.770A>T p.Y257F | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- SLC25A27 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOX10 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 218/304 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SPRR4 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 70/393 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SPTA1 | c.2705dup p.Q903Afs*5 | Frame Shift Ins (INS) | VAF 136/235 reads (58%) | called by mutect2, pindel, varscan2
- STEAP2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SULT1C3 | c.503A>T p.Y168F | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAOK1 | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR4 | c.752C>A p.A251D (on ENST00000355622 / NM_138554.5; = p.A211D on NM_003266.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TMEM225 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPO | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNNI3K | c.2029A>T p.M677L | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- TPM2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TTC4 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TXNDC16 | c.1658G>C p.G553A | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGP2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UGT2A3 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- UNC13B | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFHX3 | c.7353_7354delinsA p.P2452Qfs*76 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by pindel, varscan2*
- ZFPM2 | c.1430C>A p.P477Q | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZFYVE26 | c.3481A>T p.T1161S | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF383 | c.1203G>T p.K401N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF536 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- ZNF548 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2
- ZNF592 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZNF831 | c.2802T>A p.D934E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ABCA13 | c.4782C>G p.G1594= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV101329969; called by muse, mutect2, varscan2
- ACBD6 | c.57G>C p.L19= | Silent (SNP) | VAF 112/288 reads (39%) | called by muse, varscan2
- ADAMTS7 | c.2358G>A p.K786= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs927716529; called by muse, mutect2, varscan2
- AGBL1 | c.636G>T p.R212= | Silent (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- ASB2 | c.174G>A p.A58= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs201823942, COSV60110101; called by muse, mutect2, varscan2
- ASTN1 | c.3237G>A p.L1079= | Silent (SNP) | VAF 78/208 reads (38%) | catalogued as COSV62506174, COSV62508083; called by muse, mutect2, varscan2
- C11orf87 | c.405C>G p.P135= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV59357829; called by muse, mutect2, varscan2
- CAVIN4 | c.633G>A p.R211= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs754788547; called by muse, mutect2, varscan2
- CDH13 | c.738G>T p.R246= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV51866545; called by muse, mutect2, varscan2
- CDH9 | c.1959G>T p.R653= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV50305671; called by muse, mutect2, varscan2
- CDHR2 | c.2940C>A p.T980= | Silent (SNP) | VAF 55/176 reads (31%) | catalogued as COSV56141396; called by muse, mutect2, varscan2
- CEPT1 | c.909C>A p.I303= | Silent (SNP) | VAF 96/195 reads (49%) | called by muse, mutect2, varscan2
- CERT1 | c.1740C>A p.G580= (on ENST00000405807 / NM_001130105.1; = p.G452= on NM_005713.3) | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV54657768; called by muse, mutect2, varscan2
- CFTR | c.2106C>G p.L702= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1800102; called by muse, mutect2, varscan2
- CORIN | c.465G>C p.T155= | Silent (SNP) | VAF 79/143 reads (55%) | catalogued as COSV56694663; called by muse, mutect2, varscan2
- CPS1 | c.975C>T p.I325= | Silent (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2
- CRYGA | c.6G>T p.G2= | Silent (SNP) | VAF 121/295 reads (41%) | called by muse, mutect2, varscan2
- CYLC1 | c.51C>T p.S17= | Silent (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- EXO5 | c.1107C>G p.V369= | Silent (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- FAM98A | c.633A>T p.I211= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- FES | c.1833G>A p.L611= | Silent (SNP) | VAF 51/133 reads (38%) | called by muse, mutect2, varscan2
- FMN1 | c.3594G>T p.R1198= (on ENST00000616417 / NM_001277313.2; = p.R975= on NM_001103184.4) | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- GTF3C1 | c.1098G>T p.R366= | Silent (SNP) | VAF 150/219 reads (68%) | called by muse, mutect2, varscan2
- GUCA1B | c.345C>G p.L115= | Silent (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- H3C1 | c.198A>G p.L66= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as rs992857952; called by muse, mutect2, varscan2
- HEY1 | c.735C>T p.T245= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs762213587; called by muse, mutect2
- HHATL | c.780C>A p.A260= | Silent (SNP) | VAF 113/214 reads (53%) | catalogued as rs776383535; called by muse, mutect2, varscan2
- HLA-DQA1 | c.747C>A p.S249= | Silent (SNP) | VAF 139/337 reads (41%) | called by muse, mutect2
- HSD3B1 | c.489G>A p.E163= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV52491401; called by muse, mutect2, varscan2
- IGDCC4 | c.1512G>T p.V504= | Silent (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- IGHD | c.738C>G p.S246= | Silent (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.213T>C p.Y71= | Silent (SNP) | VAF 194/468 reads (41%) | called by muse, mutect2, varscan2
- ITGA4 | c.1752T>A p.G584= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs201546110; called by mutect2, varscan2
- ITGA8 | c.117C>T p.F39= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- KCNIP4 | c.147G>T p.S49= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- KIAA1958 | c.285G>A p.Q95= | Silent (SNP) | VAF 65/167 reads (39%) | called by muse, mutect2, varscan2
- KRT2 | c.693G>T p.G231= | Silent (SNP) | VAF 50/150 reads (33%) | catalogued as rs773480349; called by muse, varscan2
- LRRC24 | c.1407G>A p.E469= | Silent (SNP) | VAF 47/259 reads (18%) | catalogued as rs1289065487; called by muse, mutect2, varscan2
- MKI67 | c.6555G>A p.K2185= | Silent (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- NCAPD2 | c.3933G>A p.Q1311= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs1392757852; called by muse, mutect2, varscan2
- NDN | c.876C>A p.S292= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100086256, COSV59359673; called by muse, mutect2, varscan2
- NUP98 | c.1680C>A p.V560= | Silent (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- OBSCN | c.8754C>T p.F2918= | Silent (SNP) | VAF 95/296 reads (32%) | catalogued as rs1349341193; called by muse, mutect2, varscan2
- OLFM4 | c.1062C>A p.T354= | Silent (SNP) | VAF 113/198 reads (57%) | called by muse, mutect2, varscan2
- OR10W1 | c.219G>T p.L73= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV101223621; called by muse, mutect2, varscan2
- OR52N2 | c.720C>T p.F240= | Silent (SNP) | VAF 99/285 reads (35%) | called by muse, mutect2, varscan2
- PDHA2 | c.1113A>G p.S371= | Silent (SNP) | VAF 115/170 reads (68%) | called by muse, mutect2, varscan2
- PIK3C2G | c.162C>T p.Y54= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs775670304; called by muse, mutect2, varscan2
- PLCE1 | c.6717G>A p.V2239= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- POLD1 | c.2649C>T p.I883= | Silent (SNP) | VAF 127/399 reads (32%) | called by muse, mutect2, varscan2
- PRRC2A | c.15G>T p.S5= | Silent (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- PSMC5 | c.60C>A p.L20= | Silent (SNP) | VAF 86/112 reads (77%) | called by muse, mutect2, varscan2
- RYR1 | c.10989G>A p.L3663= | Silent (SNP) | VAF 143/442 reads (32%) | catalogued as COSV100617284; called by muse, mutect2, varscan2
- RYR1 | c.12141C>A p.L4047= | Silent (SNP) | VAF 142/367 reads (39%) | called by muse, mutect2, varscan2
- SCN2A | c.249C>A p.P83= | Silent (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- SEMG2 | c.453T>A p.S151= | Silent (SNP) | VAF 93/244 reads (38%) | called by muse, mutect2, varscan2
- SGSM1 | c.90G>A p.V30= | Silent (SNP) | VAF 92/132 reads (70%) | called by muse, mutect2, varscan2
- SLC36A4 | c.1275C>T p.S425= | Silent (SNP) | VAF 73/179 reads (41%) | called by muse, mutect2, varscan2
- SLC5A5 | c.1386C>A p.G462= | Silent (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1863G>T p.L621= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2, varscan2
- SPEG | c.3015C>T p.G1005= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- SPRYD3 | c.123A>T p.R41= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- SUN3 | c.102C>T p.D34= | Silent (SNP) | VAF 18/201 reads (9%) | catalogued as rs768379894, COSV52049115, COSV52049450; called by muse, mutect2, varscan2
- SYNE1 | c.3891G>T p.A1297= (on ENST00000367255 / NM_182961.4; = p.A1304= on NM_033071.3) | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as rs751975719; called by muse, mutect2, varscan2
- TBC1D8 | c.1017C>T p.I339= | Silent (SNP) | VAF 62/202 reads (31%) | called by muse, mutect2, varscan2
- TBX1 | c.735T>C p.Y245= | Silent (SNP) | VAF 91/139 reads (65%) | catalogued as rs1384305265; called by muse, mutect2, varscan2
- TMC3 | c.3072C>A p.P1024= | Silent (SNP) | VAF 73/257 reads (28%) | catalogued as rs1389063345; called by muse, mutect2, varscan2
- TMTC1 | c.1002G>T p.L334= (on ENST00000539277 / NM_001193451.2; = p.L226= on NM_175861.3) | Silent (SNP) | VAF 79/211 reads (37%) | called by muse, mutect2, varscan2
- TNXB | c.9978C>T p.S3326= (on ENST00000647633; = p.S3079= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/284 reads (34%) | called by muse, mutect2, varscan2
- TXNDC16 | c.261A>G p.E87= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- UHRF1BP1 | c.3930G>A p.P1310= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs1323973950; called by muse, mutect2, varscan2
- UNC5D | c.1233C>G p.G411= | Silent (SNP) | VAF 111/192 reads (58%) | catalogued as COSV54825858; called by muse, mutect2, varscan2
- UTP20 | c.3363G>A p.Q1121= | Silent (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2, varscan2
- VN1R2 | c.828C>T p.L276= | Silent (SNP) | VAF 58/168 reads (35%) | called by muse, varscan2
- VPS13D | c.54C>G p.V18= | Silent (SNP) | VAF 49/151 reads (32%) | called by muse, mutect2, varscan2
- AP003393.1 | n.903G>T | RNA (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- HTR1A | c.*2G>T | 3'UTR (SNP) | VAF 91/273 reads (33%) | called by muse, mutect2, varscan2
- LIM2 | c.175+51G>T | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- MIR506 | n.20C>A | RNA (SNP) | VAF 91/142 reads (64%) | called by muse, mutect2, varscan2
- NBPF7 | n.307G>C | RNA (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- OR2W5 | n.348C>T | RNA (SNP) | VAF 97/132 reads (73%) | called by muse, mutect2, varscan2
- OR4P4 | c.-1C>A | 5'UTR (SNP) | VAF 10/19 reads (53%) | catalogued as rs1402214706; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.671C>G | RNA (SNP) | VAF 51/159 reads (32%) | called by muse, mutect2, varscan2
- SSPOP | n.12964C>T | RNA (SNP) | VAF 20/48 reads (42%) | called by muse, varscan2
